Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9R4, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9R4-01A (Primary Tumor).

Reporting pathologist(s):

Sample (TYPE UNSPECIFIED) Collected

Received

HISTOLOGY

HISTOLOGY

SPECIMEN

A. Bladder tumour

B. Bladder tumour base

CLINICAL DETAILS

New TCC bladder - looks invasive!!

MACROSCOPY

A. 3 g of soft friable tissue fragments plus blood clot.

B. 2 g of soft friable tissue fragments.

MICROSCOPY

A/B.

Grade:

3 - Poorly differentiated

Growth pattern:

Mixed papillary and solid

Type:

Transitional cell carcinoma

Muscularis propria:

Present

Stromal invasion:

Invasion of muscularis propria (pT2)

Vascular channel invasion:

Not identified

Background urothelium:

Background urothelium is present which is not dysplastic

SUMMARY:

Bladder; Transitional Cell Carcinoma G3 pT2

(66F) ICD-O-3
Carcinoma, urothelial NOS
8120/3
path
Carcinoma, transitional cell NOS
8120/3
Site: Bladder NOS
067.9
JW 5/2/14

Prior Malignancy History (Y/N) Synchronous	✓	

Source: NCI Genomic Data Commons file a6a105ac-e1cb-4b6a-b8c1-e2a877f3ec8d (TCGA-ZF-A9R4.8E623BA9-F937-4DFC-97F5-7B8E5FE8498B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).